Somatic mutation profile of tumor specimen MP2PRT-PAPTAS-TMP1-A (aliquot MP2PRT-PAPTAS-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPTAS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (780 days).
Specimen MP2PRT-PAPTAS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79fe11b9-93e6-4f02-8502-6a17b282d0f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTAS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTAS-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1f1f9fe-0bb0-4f77-b74c-9d377774bd09

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 183/410 reads (45%) | catalogued as COSV57608056; called by muse, mutect2, varscan2
- IGFBP7 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV55274851; called by muse, mutect2, varscan2
- MROH2B | c.3365T>C p.I1122T | Missense Mutation (SNP) | VAF 124/346 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750426808; called by muse, mutect2, varscan2
- NOTCH1 | c.6811C>T p.P2271S | Missense Mutation (SNP) | VAF 274/706 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV53056245; called by muse, mutect2, varscan2
- UPF1 | c.1475C>T p.T492I (on ENST00000599848 / NM_001297549.2; = p.T481I on NM_002911.4) | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1246297207; called by muse, mutect2, varscan2
- DACH1 | c.2128C>A p.L710I (on ENST00000619232 / NM_001366712.1; = p.L456I on NM_004392.6) | Missense Mutation (SNP) | VAF 48/588 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- DLG5 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 17/498 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2
- PRDM15 | c.1244T>C p.L415S | Missense Mutation (SNP) | VAF 149/368 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IFIT1 | c.1185C>T p.D395= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as rs183139112, COSV65661173; called by muse, mutect2, varscan2
- STOX2 | c.1962G>A p.K654= | Silent (SNP) | VAF 81/484 reads (17%) | catalogued as rs1476012245, COSV100409125; called by muse, varscan2
